Somatic mutation profile of tumor specimen 0DWNTT from CCDI case PBCPAY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 8.5 years (3,097 days).
Specimen 0DWNTT: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cc50fd4-dcb2-4a6d-9a8a-eb3f8af53d6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/424cc105-a0c8-446b-a501-fbb03f3866f6

The open-access MAF lists 72 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 10, Intron 7, 5'UTR 3, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 177/649 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>C p.R465P (on ENST00000281708 / NM_001349798.2; = p.R385P on NM_018315.5) | Missense Mutation (SNP) | VAF 143/346 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BARHL1 | c.220T>A p.L74M | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV55038575, COSV99707462; called by muse, mutect2, varscan2
- COL16A1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs200284061; called by muse, mutect2, varscan2
- DEFB4B | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs536192108; called by muse, mutect2
- DLL4 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 137/366 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV51060961; called by muse, mutect2, varscan2
- ENKUR | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 136/348 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.214); catalogued as COSV58634235; called by muse, mutect2, varscan2
- ENPP1 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.531); catalogued as COSV62934629; called by mutect2, varscan2
- FZD10 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57473200; called by muse, mutect2, varscan2
- GRAMD1A | c.1254C>A p.H418Q | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV58768668; called by muse, mutect2, varscan2
- HECW1 | c.2192C>G p.T731R | Missense Mutation (SNP) | VAF 184/610 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.988); catalogued as COSV101223463, COSV67824903; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1204358054; called by muse, mutect2, varscan2
- MECOM | c.1994G>C p.G665A (on ENST00000468789 / NM_001105078.4; = p.G853A on NM_004991.4) | Missense Mutation (SNP) | VAF 167/667 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as rs763586979; called by muse, mutect2, varscan2
- NF1 | c.3443C>A p.A1148E | Missense Mutation (SNP) | VAF 228/524 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD095249, CM1411835; called by muse, varscan2
- PI4KA | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as rs762380493, COSV55408207; called by muse, mutect2, varscan2
- PPL | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs141706980; called by muse, mutect2, varscan2
- ROR2 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 147/383 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868585233, COSV100996172; called by muse, mutect2, varscan2
- SCN7A | c.2542C>A p.L848M | Missense Mutation (SNP) | VAF 144/802 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as COSV101313366; called by muse, mutect2, varscan2
- SERPINB13 | c.668C>G p.T223S | Missense Mutation (SNP) | VAF 162/392 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.334); catalogued as COSV99501343; called by muse, mutect2, varscan2
- SH3GL1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs377322414; called by muse, mutect2, varscan2
- TCIM | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 165/632 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs11551220; called by muse, mutect2, varscan2
- ZNF292 | c.3810T>G p.S1270R | Missense Mutation (SNP) | VAF 140/369 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs1324524369; called by muse, mutect2, varscan2
- ZNF880 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 162/519 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101424944; called by muse, mutect2, varscan2
- ZSCAN5A | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 154/431 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV54226175; called by muse, mutect2, varscan2
- ABCC4 | c.2310T>A p.G770= | Splice Region (SNP) | VAF 97/229 reads (42%) | called by muse, mutect2, varscan2
- AQP4 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASCC3 | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCM2 | c.1098G>C p.E366D | Missense Mutation (SNP) | VAF 148/542 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CELF4 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 140/347 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNGA3 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 84/998 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CRYBG1 | c.6250G>C p.D2084H | Missense Mutation (SNP) | VAF 194/439 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD1 | c.9159C>A p.D3053E (on ENST00000520002; = p.D3052E on NM_033225.6) | Missense Mutation (SNP) | VAF 341/580 reads (59%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DSG2 | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 113/361 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- EPS8 | c.2005G>C p.V669L | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- GPR31 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- KLHL35 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 281/929 reads (30%) | called by muse, mutect2, varscan2
- LCK | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 182/483 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MTR | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 130/350 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- NF1 | c.2664del p.D888Efs*14 | Frame Shift Del (DEL) | VAF 169/444 reads (38%) | called by mutect2, varscan2
- PPM1G | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 107/548 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R26 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLIT1 | c.2591G>C p.G864A | Missense Mutation (SNP) | VAF 173/417 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEC | c.1563T>A p.S521R | Missense Mutation (SNP) | VAF 170/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNN | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 181/416 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- UGGT1 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 232/1126 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF217 | c.635_656del p.S212Wfs*13 | Frame Shift Del (DEL) | VAF 158/438 reads (36%) | called by mutect2, varscan2
- ZNF345 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNFX1 | c.2273G>T p.W758L | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZSWIM6 | c.2918A>T p.Q973L | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ACKR2 | c.900C>T p.I300= | Silent (SNP) | VAF 169/528 reads (32%) | catalogued as rs200987829, COSV99825710; called by muse, mutect2, varscan2
- AFM | c.312G>T p.L104= | Silent (SNP) | VAF 98/242 reads (40%) | called by muse, mutect2, varscan2
- CUL9 | c.2409C>T p.V803= | Silent (SNP) | VAF 108/252 reads (43%) | catalogued as rs371975132; called by muse, mutect2, varscan2
- ERLIN2 | c.939C>T p.S313= | Silent (SNP) | VAF 177/654 reads (27%) | called by muse, mutect2, varscan2
- MDGA1 | c.2448C>T p.D816= | Silent (SNP) | VAF 221/562 reads (39%) | called by muse, mutect2, varscan2
- MXRA5 | c.7443C>A p.P2481= | Silent (SNP) | VAF 170/199 reads (85%) | catalogued as COSV54222567; called by mutect2, varscan2
- NF1 | c.5427G>C p.P1809= (on ENST00000358273 / NM_001042492.3; = p.P1788= on NM_000267.3) | Silent (SNP) | VAF 208/478 reads (44%) | catalogued as COSV62227094; called by muse, mutect2, varscan2
- OR9I1 | c.693A>G p.S231= | Silent (SNP) | VAF 163/544 reads (30%) | called by muse, mutect2, varscan2
- SLC2A14 | c.387C>T p.G129= | Silent (SNP) | VAF 138/366 reads (38%) | called by muse, mutect2, varscan2
- ZNF493 | c.489A>G p.K163= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- B3GALT6 | c.*53G>A | 3'UTR (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- BRMS1 | c.439-19C>G | Intron (SNP) | VAF 89/301 reads (30%) | called by muse, mutect2, varscan2
- CCDC180 | c.-81-48C>T | Intron (SNP) | VAF 84/226 reads (37%) | catalogued as rs778724968; called by muse, mutect2, varscan2
- COL27A1 | c.4809+44G>A | Intron (SNP) | VAF 92/202 reads (46%) | catalogued as rs558757842; called by muse, varscan2
- CYB5RL | c.348-55C>T | Intron (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- FAM155A | c.-63T>A | 5'UTR (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- FCGR2C | c.*38G>C | 3'UTR (SNP) | VAF 168/406 reads (41%) | called by muse, mutect2
- HSBP1L1 | c.119-89G>T | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- IFT57 | c.850-18A>G | Intron (SNP) | VAF 177/290 reads (61%) | called by muse, mutect2, varscan2
- MSANTD2P1 | n.1055C>T | RNA (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- REPS2 | c.-35G>T | 5'UTR (SNP) | VAF 42/49 reads (86%) | called by muse, mutect2, varscan2
- RNF103 | c.-954C>T | 5'UTR (SNP) | VAF 149/592 reads (25%) | called by muse, mutect2, varscan2
- YKT6 | c.459+44G>A | Intron (SNP) | VAF 70/289 reads (24%) | called by muse, mutect2, varscan2
